Somatic mutation profile of tumor specimen C3N-02761-01 (aliquot CPT0184140007) from CPTAC case C3N-02761, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 31.5 years (11,513 days).
Specimen C3N-02761-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e926bdb0-fe8a-4cbf-976b-2b394a831c89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02761-71 (Blood Derived Normal), aliquot CPT0184200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0638211-6658-4d33-870f-6ee91f8e007c

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 70/436 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs5030822, CM003061, CM941386, CM961439, COSV56544319, COSV56547906, COSV56565675; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAVIN2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 50/380 reads (13%) | catalogued as COSV58423405; called by muse, mutect2, varscan2
- COL6A5 | c.3050C>T p.S1017F | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as rs994203465; called by muse, mutect2
- TRIM41 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 50/441 reads (11%) | catalogued as COSV59319886; called by muse, mutect2, varscan2
- GABRA6 | c.422A>T p.N141I | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPCAT4 | c.794A>T p.D265V | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MATR3 | c.1235_1236dup p.Y413Dfs*8 | Frame Shift Ins (INS) | VAF 20/189 reads (11%) | called by mutect2, pindel
- PCBP1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SPHK2 | c.1703T>A p.L568Q | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDP2 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- THNSL2 | c.994T>G p.S332A | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF23 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDYL | c.1143G>C p.T381= (on ENST00000328908 / NM_001368125.1; = p.T327= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- DCXR | c.39C>T p.T13= | Silent (SNP) | VAF 84/545 reads (15%) | called by muse, mutect2, varscan2
- IL9R | c.345T>C p.S115= | Silent (SNP) | VAF 91/632 reads (14%) | called by muse, mutect2, varscan2
- OR7A5 | c.108G>T p.L36= | Silent (SNP) | VAF 14/393 reads (4%) | catalogued as COSV100457723; called by muse, mutect2
- TMEM150A | c.120C>T p.Y40= (on ENST00000334462 / NM_001031738.3; = p.T10I on NM_153342.3) | Silent (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2
- USP37 | c.863+1178A>C | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
